TCGA case TCGA-CI-6620 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b26143d3-d458-4d5c-8446-fd2f05707352

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 41 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 41.9 years (15,322 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IVA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Days to last follow up: 1,009 days (2.8 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Oxaliplatin; Days to treatment start: 39 days; Days to treatment end: 160 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 39 days; Days to treatment end: 160 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 42.2 years (15,412 days); Days to diagnosis: 90 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 90 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 184 days; Disease response: With Tumor.
- Days to follow up: 1,009 days (2.8 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CI-6620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.5; Intermediate dimension: 0.3; Shortest dimension: 0.3.
  Slide TCGA-CI-6620-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 65; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-CI-6620-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: TSS informed the BCR that the patient starting receiving chemotherapy (Leucovorin, Fluorouracil and Oxaliplatin) 1 month prior to TCGA cancer procurement and continued after surgery.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,009 days; disease-specific survival: no event (censored), 1,009 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 90 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CI-6620-01A-11D-1825-01): tumor purity 0.45, ploidy 3.7, whole-genome doublings 1.
